Somatic mutation profile of tumor specimen TCGA-AB-2897-03A (aliquot TCGA-AB-2897-03A-01W-0733-08) from TCGA case TCGA-AB-2897, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute promyelocytic leukaemia, t(15;17)(q22;q11-12); Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.4 years (18,413 days).
Specimen TCGA-AB-2897-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c87a6de-d57b-4c81-9d9c-09643cf0b633.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2897-11A (Solid Tissue Normal), aliquot TCGA-AB-2897-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1730e1cf-213d-40de-955d-4133fd176bb9

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AK9 | c.5683C>T p.H1895Y | Missense Mutation (SNP) | VAF 94/257 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV69851318; called by muse, mutect2, varscan2
- MSRB1 | c.148A>G p.I50V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV51906684; called by muse, mutect2, varscan2
- PHIP | c.630G>T p.W210C | Missense Mutation (SNP) | VAF 55/400 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51504625; called by muse, mutect2, varscan2
- CALR | c.397+2dup p.X133_splice | Splice Site (INS) | VAF 27/250 reads (11%) | called by mutect2, pindel, varscan2
